Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4HB, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4HB-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: Stomach Ca.

GROSS:

Specimen state: Fresh

Operation: Laparoscopic distal gastrectomy
Laparoscopic cholecystectomy

Measurement: Greater curvature 17.0 cm
Lesser curvature 9.0 cm
Proximal resection margin 13.0 cm
Distal resection margin 5.3 cm
Duodenum 0.3 cm

Lesion: An ulcerofungating mass
Tumor size: 3.0 x 3.0 x 1.3 cm
Location: Anterior wall side of mid-antrum
Tumor type: AGC (Borrmann type II)
From proximal resection margin - 2.0 cm
From distal resection margin - 5.0 cm

Gross serosal invasion: No

Gallbladder: 9.2 cm in length, 3.0 cm in diameter

Lesion: Stone: Four, black and hard
(1.5 x 1.1 x 0.2 cm in aggregates, up to 0.6 x 0.5 x 0.2 cm)

Serosal surface: Yellowish pink

Mucosal surface: Brown to yellow, velvety

Wall: 0.2 cm in thickness

Representative sections submitted

ICD-0-3

adenocarcinoma, diffuse type 8145/3

Site: Stomach, antrum c16.3

Gross photo: Present

Blocks

hw
9/27/12

T1-4, TB, tumor and surrounding tissue x 5

A, NB, antrum mucosa x 2

B, body mucosa x 1

P, proximal resection margin x 1

D, distal resection margin x 1

[page 2 of 3]
LN1-2, superior gastric lymph nodes x 2

LN3-4, inferior gastric lymph nodes x 2

LN5, '1' lymph nodes x 1

LN6, '5' lymph nodes x 1

LN7, '6' lymph nodes x 1

LN8, '7' lymph nodes x 1

LN9, '8' lymph nodes x 1

LN10, '9' lymph nodes x 1

LN11, '11p' lymph nodes x 1

LN12, '12' lymph nodes x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Adenocarcinoma, Diffuse type

Depth of tumor invasion:

T2: Muscularis propria (MP)

Margins: Proximal resection margin (-)

Distal resection margin (-)

Lauren classification: Diffuse

Ming classification (Growth pattern): Expanding

Lymphoid reaction: Moderate

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Absent

Lymph node metastasis: Present (5/43)

Pathologic stage: pT2N2Mx (AJCC 7th edition)

SPECIAL STAIN: Cresyl Violet stain reveals no H. pylori.

DIAGNOSIS:

Stomach, mid-antrum, laparoscopic distal gastrectomy:

Adenocarcinoma, Diffuse type

Lymph node, perigastric, laparoscopic distal gastrectomy:

Superior gastric: Metastatic carcinoma, primary in stomach (2/13)

Inferior gastric: Metastatic carcinoma, primary in stomach (3/18)

Lymph node, regional, biopsy:

Labeled as '1': No lymph node

[page 3 of 3]
Labeled as '5': No lymph node
Labeled as '6': No tumor present (0/9)
Labeled as '7': No lymph node
Labeled as '8': No tumor present (0/1)
Labeled as '9': No tumor present (0/1)
Labeled as '11p': No lymph node
Labeled as '12': No tumor present (0/1)

Gallbladder, laparoscopic cholecystectomy:

Autolysis

Cholelithiasis

9/20/12

Source: NCI Genomic Data Commons file f5ca2d26-09f3-46ab-9d00-be7b7e92f9f1 (TCGA-HU-A4HB.D81144CF-B95D-4373-ACC6-01B9F092A9D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).